Somatic mutation profile of cancer-model specimen HCM-BROD-0009-C25-85A (3D Organoid, passage 11; aliquot HCM-BROD-0009-C25-85A-01D-A786-36), derived from the metastatic tumor of HCMI case HCM-BROD-0009-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 49.4 years (18,041 days).
Specimen HCM-BROD-0009-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 11.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 70a43944-a1e1-4976-9eee-55b97d57d6eb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0009-C25-10A (Blood Derived Normal), aliquot HCM-BROD-0009-C25-10A-01D-A78W-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8ab61bda-7f6d-4a83-a52c-5bba9942d48d

The open-access MAF lists 83 somatic variants for this specimen: 49 protein-altering or splice-affecting, 23 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 23, Intron 4, RNA 4, Nonsense Mutation 2, Frame Shift Ins 2, Splice Site 1, 5'UTR 1, 3'Flank 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 519/818 reads (63%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.814G>A p.V272M | Missense Mutation (SNP) | VAF 687/689 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912657, CM130241, CM920676, COSV52661812, COSV52677483, COSV52701127; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TTN | c.47550G>A p.W15850* (on ENST00000591111; = p.W8426* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 16/152 reads (11%) | catalogued as rs794729271; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACVR1C | c.1330A>G p.I444V | Missense Mutation (SNP) | VAF 52/108 reads (48%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as rs1293773025; called by muse, varscan2
- ACVR1C | c.1267C>A p.P423T | Missense Mutation (SNP) | VAF 60/132 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.373); catalogued as COSV54644170; called by muse, varscan2
- ADCY6 | c.263C>T p.A88V | Missense Mutation (SNP) | VAF 311/647 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.139); catalogued as rs988684162; called by muse, mutect2, varscan2
- ATP10D | c.3670G>A p.D1224N | Missense Mutation (SNP) | VAF 206/424 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.58); catalogued as COSV56711130; called by muse, mutect2, varscan2
- CCR3 | c.964A>G p.M322V | Missense Mutation (SNP) | VAF 17/296 reads (6%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs1314419556; called by muse, mutect2
- COL11A1 | c.3232G>T p.G1078* | Nonsense Mutation (SNP) | VAF 156/929 reads (17%) | catalogued as COSV62190299; called by muse, mutect2, varscan2
- DGKG | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 158/301 reads (52%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as rs375556558; called by muse, mutect2
- FAM124B | c.250C>T p.R84C | Missense Mutation (SNP) | VAF 175/355 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as rs1280865122, COSV54739336; called by muse, mutect2, varscan2
- GPR158 | c.3343G>T p.G1115W | Missense Mutation (SNP) | VAF 382/748 reads (51%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as COSV66265522; called by muse, mutect2, varscan2
- HMCN1 | c.4571A>C p.Q1524P | Missense Mutation (SNP) | VAF 195/382 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV54903968; called by muse, mutect2, varscan2
- HSPB1 | c.126G>T p.W42C | Missense Mutation (SNP) | VAF 463/978 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs896004429; called by muse, mutect2, varscan2
- IQSEC3 | c.1384G>A p.G462R (on ENST00000538872 / NM_001170738.2; = p.G159R on NM_015232.1) | Missense Mutation (SNP) | VAF 56/275 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs782335400, COSV58291376; called by muse, mutect2, varscan2
- KCNQ2 | c.403G>A p.V135M | Missense Mutation (SNP) | VAF 214/416 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775649577; called by muse, mutect2, varscan2
- KDM5C | c.4250A>T p.H1417L | Missense Mutation (SNP) | VAF 185/575 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV64765165; called by muse, mutect2, varscan2
- KRTAP10-1 | c.97G>A p.A33T | Missense Mutation (SNP) | VAF 19/486 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.02); catalogued as rs782205780, COSV59973831; called by muse, mutect2
- LRRC8D | c.520A>G p.I174V | Missense Mutation (SNP) | VAF 28/410 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.292); catalogued as rs752218122; called by muse, mutect2
- MAP10 | c.2228A>C p.K743T | Missense Mutation (SNP) | VAF 70/156 reads (45%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.876); catalogued as COSV69363590; called by muse, mutect2, varscan2
- NOC2L | c.964C>T p.R322W | Missense Mutation (SNP) | VAF 76/542 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs367591999; called by muse, mutect2, varscan2
- OR11H1 | c.691G>T p.G231C | Missense Mutation (SNP) | VAF 508/1190 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as rs537405197, COSV53271623; called by muse, mutect2, varscan2
- OR8K1 | c.768G>T p.M256I | Missense Mutation (SNP) | VAF 84/231 reads (36%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); catalogued as COSV54402096; called by muse, mutect2, varscan2
- PCLO | c.3609C>G p.D1203E | Missense Mutation (SNP) | VAF 13/510 reads (3%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); catalogued as rs1443839197; called by muse, mutect2
- SCN4A | c.1538C>T p.S513L | Missense Mutation (SNP) | VAF 101/254 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs1227159244, COSV71125975; called by muse, mutect2
- SCN9A | c.5837C>A p.T1946K (on ENST00000303354; = p.T1935K on NM_002977.3) | Missense Mutation (SNP) | VAF 192/494 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV57604382; called by mutect2, varscan2
- SRRM4 | c.1462C>T p.R488W | Missense Mutation (SNP) | VAF 230/518 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV57428953; called by muse, mutect2, varscan2
- ZNF462 | c.5617G>T p.D1873Y | Missense Mutation (SNP) | VAF 285/285 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV52952959; called by muse, mutect2, varscan2
- ABHD2 | c.1248C>A p.D416E | Missense Mutation (SNP) | VAF 18/436 reads (4%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.01); called by muse, mutect2
- ADGRV1 | c.6454G>T p.V2152L | Missense Mutation (SNP) | VAF 43/141 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, varscan2
- ARAP2 | c.2622C>G p.F874L | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.65); called by muse, mutect2
- DMC1 | c.520G>C p.A174P | Missense Mutation (SNP) | VAF 312/769 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- EPC2 | c.1210G>C p.A404P | Missense Mutation (SNP) | VAF 26/584 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.505); called by muse, mutect2
- ERVV-1 | c.545G>A p.R182H | Missense Mutation (SNP) | VAF 409/514 reads (80%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- GARNL3 | c.2583A>T p.R861S | Missense Mutation (SNP) | VAF 14/410 reads (3%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.966); called by muse, mutect2
- GK2 | c.279G>T p.Q93H | Missense Mutation (SNP) | VAF 156/321 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRIA2 | c.608dup p.E204Gfs*9 | Frame Shift Ins (INS) | VAF 50/143 reads (35%) | called by pindel, varscan2
- IGFBP7 | c.818C>T p.P273L | Missense Mutation (SNP) | VAF 29/195 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- IGFBP7 | c.267G>C p.K89N | Missense Mutation (SNP) | VAF 52/724 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.054); called by muse, mutect2
- KDM5C | c.4249C>A p.H1417N | Missense Mutation (SNP) | VAF 185/576 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- KIF5B | c.2019G>T p.Q673H | Missense Mutation (SNP) | VAF 75/165 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- LTBP2 | c.3477G>T p.Q1159H | Missense Mutation (SNP) | VAF 659/662 reads (100%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- NBAS | c.3869A>C p.Q1290P | Missense Mutation (SNP) | VAF 414/836 reads (50%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- NRDE2 | c.1918T>C p.F640L | Missense Mutation (SNP) | VAF 476/477 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- OR11H1 | c.690G>T p.L230F | Missense Mutation (SNP) | VAF 508/1193 reads (43%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- POLR2H | c.381_382dup p.D128Gfs*18 | Frame Shift Ins (INS) | VAF 138/402 reads (34%) | called by pindel, varscan2
- SI | c.3759+1G>T p.X1253_splice | Splice Site (SNP) | VAF 45/310 reads (15%) | called by muse, mutect2, varscan2
- SPART | c.1154G>T p.R385L | Missense Mutation (SNP) | VAF 83/265 reads (31%) | SIFT tolerated (0.4); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- TDRD15 | c.3492A>T p.R1164S | Missense Mutation (SNP) | VAF 60/119 reads (50%) | SIFT tolerated (0.69); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ABCD2 | c.594T>C p.N198= | Silent (SNP) | VAF 15/325 reads (5%) | called by muse, mutect2
- ABCG5 | c.1329C>T p.P443= | Silent (SNP) | VAF 558/1133 reads (49%) | catalogued as rs201620171; called by muse, mutect2, varscan2
- ANKRD13B | c.1449C>T p.F483= | Silent (SNP) | VAF 17/530 reads (3%) | catalogued as rs1336820028; called by muse, mutect2
- BRCA2 | c.2043A>G p.V681= | Silent (SNP) | VAF 117/117 reads (100%) | catalogued as rs747363339; ClinVar: likely benign; called by muse, mutect2, varscan2
- CHRNA4 | c.489C>A p.I163= | Silent (SNP) | VAF 752/1535 reads (49%) | catalogued as COSV64719349; called by muse, mutect2, varscan2
- COL6A5 | c.1512C>T p.D504= | Silent (SNP) | VAF 18/314 reads (6%) | called by muse, mutect2
- COL6A5 | c.4086T>C p.H1362= | Silent (SNP) | VAF 27/176 reads (15%) | catalogued as rs987189916; called by muse, mutect2, varscan2
- GGT5 | c.1596C>T p.Y532= | Silent (SNP) | VAF 296/612 reads (48%) | catalogued as rs745874439, COSV54071049; called by muse, mutect2, varscan2
- GLRX5 | c.369C>T p.D123= | Silent (SNP) | VAF 36/600 reads (6%) | called by muse, mutect2
- IQANK1 | c.24C>A p.P8= | Silent (SNP) | VAF 17/607 reads (3%) | called by muse, mutect2
- KDM3B | c.2121C>T p.G707= | Silent (SNP) | VAF 159/322 reads (49%) | called by muse, mutect2, varscan2
- KRT86 | c.240C>T p.T80= | Silent (SNP) | VAF 436/1379 reads (32%) | called by muse, mutect2, varscan2
- MACF1 | c.21510A>T p.G7170= (on ENST00000372915; = p.G5215= on NM_012090.5) | Silent (SNP) | VAF 262/561 reads (47%) | called by muse, mutect2, varscan2
- NR1H4 | c.1065G>A p.P355= (on ENST00000551379 / NM_001206993.2; = p.P341= on NM_005123.4) | Silent (SNP) | VAF 293/606 reads (48%) | catalogued as rs569479207, COSV51857715; called by muse, mutect2, varscan2
- NYAP2 | c.1278C>T p.P426= | Silent (SNP) | VAF 72/147 reads (49%) | catalogued as rs1305682005; called by muse, mutect2, varscan2
- OR5AN1 | c.594C>T p.V198= | Silent (SNP) | VAF 182/362 reads (50%) | catalogued as COSV58321558, COSV58321835; called by muse, mutect2, varscan2
- RPL3 | c.477C>T p.V159= | Silent (SNP) | VAF 298/563 reads (53%) | catalogued as rs766432864; called by muse, mutect2, varscan2
- SIGLEC11 | c.192C>T p.D64= | Silent (SNP) | VAF 530/584 reads (91%) | catalogued as rs762185501; called by muse, mutect2, varscan2
- SLC39A11 | c.45C>T p.T15= | Silent (SNP) | VAF 149/948 reads (16%) | called by muse, mutect2, varscan2
- SLCO1C1 | c.1092T>C p.V364= | Silent (SNP) | VAF 140/291 reads (48%) | called by muse, mutect2, varscan2
- SMARCA4 | c.4254C>T p.D1418= | Silent (SNP) | VAF 454/455 reads (100%) | catalogued as rs370380553; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZFHX4 | c.4212G>A p.L1404= | Silent (SNP) | VAF 166/368 reads (45%) | catalogued as COSV51500925; called by muse, mutect2, varscan2
- ZNF598 | c.1062C>T p.A354= | Silent (SNP) | VAF 334/689 reads (48%) | catalogued as rs752141278; called by muse, mutect2, varscan2
- AC018563.1 | n.682G>A | RNA (SNP) | VAF 55/159 reads (35%) | catalogued as rs1401741243; called by muse, mutect2, varscan2
- ATP6V0B | c.67+9G>A | Intron (SNP) | VAF 36/60 reads (60%) | called by muse, mutect2, varscan2
- C4orf50 | c.-571C>A | 5'UTR (SNP) | VAF 21/409 reads (5%) | called by muse, mutect2
- FAM153CP | chr5:178056087 C>T | 3'Flank (SNP) | VAF 390/942 reads (41%) | catalogued as rs762773407; called by muse, mutect2, varscan2
- MIR1208 | n.26G>T | RNA (SNP) | VAF 28/569 reads (5%) | called by muse, mutect2
- MIR1208 | n.27G>C | RNA (SNP) | VAF 28/557 reads (5%) | called by muse, mutect2
- MMP16 | chr8:88327991 G>T | 5'Flank (SNP) | VAF 117/261 reads (45%) | called by muse, mutect2, varscan2
- NFIC | c.97-22094C>G | Intron (SNP) | VAF 168/169 reads (99%) | catalogued as rs1007278796; called by muse, mutect2, varscan2
- PLEKHH3 | c.2014-121C>A | Intron (SNP) | VAF 19/155 reads (12%) | called by muse, mutect2, varscan2
- PNKD | c.237-16524G>A | Intron (SNP) | VAF 434/862 reads (50%) | called by muse, mutect2, varscan2
- SNORD115-7 | n.52C>A | RNA (SNP) | VAF 51/528 reads (10%) | called by muse, mutect2, varscan2
